TCGA case TCGA-36-2543 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: BC Cancer Agency. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/73b63d07-0c1d-4bf2-bf11-b183e090e200

Demographics
Sex at birth: female; Age at index: 85 years; Vital status: Dead; Days to death: 68 days.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 85.5 years (31,211 days); Year of diagnosis: 2008; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Residual disease: R1.
   Pathology details: Residual tumor measurement: >20 mm.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 85.5 years (31,238 days); Days to diagnosis: 27 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 27 (post initial treatment): Progression or recurrence: Yes; Days to progression: 27 days.
- Days to follow up: 68 days; Disease response: With Tumor.
- ECOG performance status: 3; Timepoint: Other.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-36-2543-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-36-2543-01A-01-BS1: Section location: Bottom; Percent tumor cells: 77; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 8.
  Slide TCGA-36-2543-01A-01-TS1: Section location: Top; Percent tumor cells: 81; Percent tumor nuclei: 90; Percent normal cells: 8; Percent necrosis: 3; Percent stromal cells: 8.
- Sample TCGA-36-2543-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-36-2543-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 68 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 68 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 27 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-36-2543-01A-01D-1043-01): tumor purity 0.58, ploidy 3.28, whole-genome doublings 1.
